Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A7FD, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A7FD-01A (Primary Tumor).

[page 1 of 3]
Patient:
MRN:
DOB:
SEX: Male

SURGICAL PATHOLOGY, COMPREHENSIVE

Status: Final result Released

Surgical Pathology

Inquiry:
Fax:

Surgical Pathology Report

Specimen Date:
In Lab Date:
Report Date:

Patient:

MRN:

Encounter #:
Location:
Age/ Sex:

CLINICAL INFORMATION:
Prostate cancer.

INTRAOPERATIVE DIAGNOSIS:
A-C Frozen section diagnosis:

Soft tissue only.

Reported to:

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "posterior apical margin" and consists of a 0.1 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: A1 FSC.

B. Received fresh, the specimen is labeled "right posterior para-apical margin" and consists of a 0.2 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: B1 FSC.

C. Received fresh, the specimen is labeled "right base margin" and consists of a 0.4 x 0.3 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: C1 FSC.

D. Received fresh, the specimen is labeled "prostate gland and seminal vesicles", and consists of a 32.9 gram radical prostatectomy specimen including a 4.0 x 3.5 x 3.0 cm prostate, a 3.0 x 1.5 x 1.0 cm left seminal vesicle, a 2.5 x 0.5 x 0.5 cm left vas deferens, a 2.5 x 2.0 x 0.5 cm right seminal vesicle, and a 2.0 x 0.5 x 0.5 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to D respectively. Section B is submitted for research. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted entirely. Summary of sections: D1-RSV and

ICD-6-3
Adenocarcinoma, acinar 8140/3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
9/26/13

[page 2 of 3]
LSV, D2-anterior base, D3-posterior base, D4-anterior apex, D5-posterior apex, D6-AR, D7-AL, D8-CRA, D9-CRP, D10-CLA, D11-CLP (missing ink), D12-DR, D13-DL. (Note: R=Right; L=Left; A=Anterior; P=posterior)

E. Received fresh, the specimen is labeled "pelvic lymph nodes" and consists of a 5.0 x 5.0 x 1.0 cm piece of fibroadipose tissue and lymph nodes. 100% submitted. Summary of sections: E1-E3.

F. Received fresh, the specimen is labeled "anterior prostatic fat" and consists of an aggregate of fibroadipose tissue measuring 4.5 x 1.5 x 0.5 cm 100% submitted. Summary of sections: F1.

DIAGNOSIS:

A. Prostate, posterior apical margin, biopsy:
Fibromuscular tissue.

No prostatic glands or carcinoma identified.

B. Prostate, right posterior para-apical margin, biopsy:
Fibromuscular tissue and nerve.

No prostatic glands or carcinoma identified.

C. Prostate, right base margin, biopsy:

Fibromuscular tissue and nerve.

No prostatic glands or carcinoma identified.

D. Prostate and seminal vesicles, radical prostatectomy:

Prostatic adenocarcinoma, Gleason score 3+4=7.

Tumor primarily involves the right posterior region from apex to base,

with involvement of the right anterior and left posterior regions towards the apex.

Established extraprostatic extension is present on the right side posterolaterally from mid to base.

Focus suspicious for angiolymphatic invasion.

Seminal vesicles and all surgical margins are negative for tumor.

E. Lymph nodes, pelvis, excision:

Sixteen lymph nodes are negative for metastatic carcinoma (0/16).

F. Soft tissue, anterior prostate, excision:

Fibroadipose tissue.

No lymph nodes, prostatic tissue, or carcinoma identified.

SYNOPSIS DIAGNOSIS:

Histologic Type: (conventional, not otherwise specified)	Adenocarcinoma
	Primary Pattern: Grade 3
	Secondary Pattern: Grade 4
	Total Gleason Score: 7
Tumor Quantitation: prostatic tissue involved by tumor: 7%	Proportion (percent) of
Pathologic Staging (pTNM): extension	pT3a: Extraprostatic
node metastasis	pN0: No regional lymph
nodes examined: 16	Number of regional lymph
nodes involved: 0	Number of regional lymph
cannot be assessed	pMx: Distant metastasis

[page 3 of 3]
Margi ns:	Margi ns uni nvol ved by
i nvasi ve carci noma	
Extr aprost atic Extensi on:	Present
Seri nal Vesic le Invasi on:	Absent
Peri neural Invasi on:	Present
Lymphatic (Small Vessel) Invasi on (L):	Indet ermi nat e

**** Electronically Signed Out ****

At t endi ng Pat hol ogi st

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

ICD9 Codes: A-F: 185
Billing Codes: A-C: (Inpatient)

A-C, F;

D.

道

SNOWED:

S i des: A-2, B-2, C-2, D-13, E-4, F-1

Resulting Agency

Specimen Collected: Last Resulted:

Order Information Lab Collection Information, Order Information, Order Providers

Source: NCI Genomic Data Commons file a920b858-1e80-48f9-adb3-dfc988440c78 (TCGA-KC-A7FD.15E27E53-1EF7-495A-A000-F10108E653C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).